Somatic mutation profile of tumor specimen C3L-00796-01 (aliquot CPT0065750009) from CPTAC case C3L-00796, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.2 years (24,549 days).
Specimen C3L-00796-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b03a347b-dc24-47f4-a7d5-99439107be7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00796-31 (Blood Derived Normal), aliquot CPT0067670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/697c8c1b-8fbc-4dcc-8756-a213801da1fe

The open-access MAF lists 98 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Frame Shift Del 6, Intron 5, 3'UTR 4, Frame Shift Ins 3, Nonsense Mutation 2, In Frame Del 2, 5'UTR 2, Nonstop Mutation 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.1564A>G p.S522G (on ENST00000506720 / NM_001322402.2; = p.S454G on NM_015236.6) | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1002460440; called by muse, mutect2, varscan2
- ADRA1B | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs747586034; called by muse, mutect2, varscan2
- BAP1 | c.510T>G p.F170L | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56238154; called by muse, mutect2, varscan2
- C3 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 129/471 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1443451793, COSV55570277; called by muse, mutect2, varscan2
- CCDC168 | c.12874C>A p.Q4292K | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs184367436; called by muse, mutect2, varscan2
- CCDC40 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99481770; called by muse, mutect2, varscan2
- DNAH3 | c.5299T>C p.W1767R | Missense Mutation (SNP) | VAF 101/432 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423975629; called by muse, mutect2, varscan2
- DONSON | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs756425637; called by muse, mutect2, varscan2
- GART | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV67818076; called by muse, mutect2, varscan2
- IRF1 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.1); catalogued as COSV55378610; called by muse, mutect2, varscan2
- KIAA1109 | c.11756G>A p.S3919N | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774701020; called by muse, mutect2, varscan2
- NES | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV63960457; called by muse, mutect2, varscan2
- NGDN | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768047922; called by muse, mutect2, varscan2
- NMD3 | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV63618086, COSV63618776; called by muse, mutect2, varscan2
- NPY1R | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as rs1342767208; called by muse, mutect2, varscan2
- OAZ1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs969846397; called by muse, mutect2, varscan2
- SLC2A10 | c.1073G>T p.R358M | Missense Mutation (SNP) | VAF 221/837 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1471275289; called by muse, mutect2, varscan2
- SP4 | c.1336_1341del p.L446_Q447del | In Frame Del (DEL) | VAF 65/216 reads (30%) | catalogued as rs773045711; called by mutect2, pindel, varscan2
- TP53BP2 | c.959A>G p.K320R (on ENST00000343537 / NM_001031685.3; = p.K191R on NM_005426.2) | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1263305737; called by muse, mutect2, varscan2
- TTC23L | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV101551112; called by muse, mutect2, varscan2
- UMAD1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs768967798; called by muse, mutect2, varscan2
- ZNF831 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV64038424; called by muse, mutect2, varscan2
- ASAH1 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 113/377 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ASCC3 | c.2372G>C p.R791T | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS7 | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BUB1B | c.2395C>A p.Q799K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CCP110 | c.2484dup p.D829Rfs*44 | Frame Shift Ins (INS) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- CEP41 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 154/592 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- COL6A6 | c.4151G>T p.C1384F | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSF1R | c.2382T>G p.I794M | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS3 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DHX29 | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DOCK7 | c.6128T>C p.V2043A (on ENST00000635253 / NM_001367561.1; = p.V2012A on NM_033407.3) | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- EIF5B | c.984A>C p.K328N | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- EP400 | c.8798T>A p.L2933Q | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FGA | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXK2 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- FOXN3 | c.899G>T p.G300V (on ENST00000261302; = p.G278V on NM_005197.4) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- GTF2H3 | c.124_125insGGGA p.M42Rfs*50 | Frame Shift Ins (INS) | VAF 38/155 reads (25%) | called by mutect2, pindel, varscan2
- HNRNPK | c.1033T>A p.W345R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IFIT1B | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT172 | c.4756-6C>T | Splice Region (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- MVD | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- NPTX1 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- NR2F2 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD2 | c.5932A>T p.S1978C | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PTGES | c.205del p.L69Sfs*60 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- PTGR1 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RAB11FIP1 | c.1873T>G p.S625A | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2
- RRP1B | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- SIPA1L3 | c.3277_3278del p.L1093Tfs*97 | Frame Shift Del (DEL) | VAF 52/242 reads (21%) | called by pindel, varscan2
- SMG1 | c.3055A>C p.N1019H | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNX2 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.433); called by muse, varscan2
- SPATA2L | c.1111T>C p.C371R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SREBF1 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- STAG2 | c.2946del p.F982Lfs*14 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by pindel, varscan2
- STMN3 | c.23A>C p.Y8S | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TDP1 | c.1518_1519delinsT p.K506Nfs*27 | Frame Shift Del (DEL) | VAF 54/270 reads (20%) | called by pindel, varscan2*
- TMEM132A | c.1012del p.S338Pfs*24 (on ENST00000453848 / NM_178031.3; = p.S338Pfs*25 on NM_017870.4) | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- TMEM60 | c.183dup p.K62* | Frame Shift Ins (INS) | VAF 22/93 reads (24%) | called by mutect2, pindel, varscan2
- TRIM37 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNDC11 | c.490A>T p.N164Y | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5A | c.2273_2281del p.L758_R760del | In Frame Del (DEL) | VAF 11/125 reads (9%) | called by mutect2, pindel
- USHBP1 | c.965_966del p.K322Rfs*4 | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | called by mutect2, pindel, varscan2
- WLS | c.1625A>G p.*542Wext*17 | Nonstop Mutation (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- ZFP36 | c.13T>C p.Y5H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF691 | c.362G>T p.G121V (on ENST00000372502; = p.G90V on NM_015911.3) | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ACER2 | c.585C>T p.D195= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as COSV61820824; called by muse, mutect2, varscan2
- AHSG | c.12C>T p.L4= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as rs144256924, COSV99890190; called by muse, mutect2, varscan2
- AVL9 | c.879T>C p.T293= | Silent (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2358C>T p.R786= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as rs369254131; called by muse, mutect2
- CYC1 | c.210G>A p.G70= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- FAM234B | c.1236G>A p.R412= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as rs377281119; called by muse, mutect2, varscan2
- FAM89B | c.174C>T p.A58= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- FOXN3 | c.900G>C p.G300= (on ENST00000261302; = p.G278= on NM_005197.4) | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, varscan2
- LSR | c.1878C>T p.T626= (on ENST00000361790; = p.T607= on NM_015925.6) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs748717222; called by muse, mutect2, varscan2
- MEF2D | c.1464G>A p.G488= | Silent (SNP) | VAF 54/239 reads (23%) | catalogued as rs139959650, COSV61729751; called by muse, mutect2, varscan2
- MXD3 | c.534G>C p.L178= | Silent (SNP) | VAF 80/222 reads (36%) | catalogued as rs141349755; called by muse, mutect2, varscan2
- PRDM2 | c.1287T>C p.D429= | Silent (SNP) | VAF 64/250 reads (26%) | called by muse, mutect2, varscan2
- RAI1 | c.5025G>A p.V1675= | Silent (SNP) | VAF 125/412 reads (30%) | called by muse, mutect2, varscan2
- SAMD14 | c.885C>A p.P295= (on ENST00000330175 / NM_001257359.2; = p.P323= on NM_174920.4) | Silent (SNP) | VAF 49/167 reads (29%) | called by muse, mutect2, varscan2
- TRIM37 | c.93C>T p.C31= | Silent (SNP) | VAF 66/308 reads (21%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.2946A>G p.G982= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- WDFY3 | c.10071A>G p.R3357= | Silent (SNP) | VAF 58/157 reads (37%) | called by muse, mutect2, varscan2
- ZNF691 | c.363C>T p.G121= (on ENST00000372502; = p.G90= on NM_015911.3) | Silent (SNP) | VAF 65/307 reads (21%) | catalogued as rs1331408677; called by muse, mutect2, varscan2
- ZNF780A | c.1638A>G p.Q546= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as rs1332243672; called by muse, mutect2, varscan2
- ANKS6 | c.*4023T>C | 3'UTR (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- AR | c.*45dup | 3'UTR (INS) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- C1orf112 | chr1:169795101 ins T | 5'Flank (INS) | VAF 47/166 reads (28%) | catalogued as rs899180309; called by mutect2, pindel, varscan2
- GNA12 | c.310-19744C>T | Intron (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- HSP90B1 | c.152+86A>C | Intron (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- ISYNA1 | c.609+14C>T | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as rs1055154489; called by muse, varscan2
- KLF6 | c.*712A>G | 3'UTR (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
- KLHL14 | c.-44+516_-44+518del | Intron (DEL) | VAF 4/24 reads (17%) | catalogued as rs780568428; called by mutect2, pindel
- LY6H | c.68-97G>A | Intron (SNP) | VAF 26/92 reads (28%) | catalogued as rs1289890820; called by muse, varscan2
- PAQR4 | c.*1464C>G | 3'UTR (SNP) | VAF 35/146 reads (24%) | catalogued as rs1303587446; called by muse, mutect2, varscan2
- UBQLN2 | c.-12A>C | 5'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- UBQLN2 | c.-11C>A | 5'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs1190566023; called by muse, mutect2, varscan2
